Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5889, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5889-01A (Primary Tumor).

[page 1 of 5]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Left renal mass with thrombus, left kidney tumor.

Specimens Submitted:

- 1: SP: Caval wall, biopsy
- 2: SP: Kidney and adrenal gland, left, radical nephrectomy
- 3: SP: Vena cava, additional, biopsy
- 4: SP: Lymph nodes, left perihilar, resection
- 5: SP: Lymph nodes, paraaortic, resection
- 6: SP: Lymph nodes, aortocaval, resection
- 7: SP: Hernia sac, abdomen, repair

DIAGNOSIS:

1. SP: Caval wall, biopsy
- Portion of vein with a detached cluster of atypical cells admixed with fibrin in the lumen (see comment)
2. SP: Kidney and adrenal gland, left, radical nephrectomy:
- Tumor Type:
- Renal cell carcinoma, unclassified, with papillary features and high nuclear grade (see comment)
- Tumor Size:
- Greatest diameter is 8.5 cm.
- With multiple satellite nodules
- Local Invasion (for renal cortical types):
- Extends through renal capsule but confined within Gerota's fascia
- Extends into renal pelvis
- Involves renal hilar fat
- Renal Vein Invasion:
- Identified
- Extensive vascular invasion is present
- Surgical Margins:
- Tumor present at renal vein margin
- Non-Neoplastic Kidney:
- Unremarkable
- Renal papillary adenoma (0.2cm in greatest dimension)
- Adrenal Gland:
- Carcinoma involves the periadrenal soft tissue and abuts the capsule of the adrenal gland
- Lymph Nodes:

[page 2 of 5]
Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

3. SP: Vena cava, additional, biopsy:

-Portion of vein with detached atypical cells admixed with fibrin in the lumen, favor reactive: no definite tumor seen (see comment)

4. SP: Lymph nodes, left perihilar, resection:

Lymph Nodes:

Number of nodes examined:10

Number of metastatic nodes:8

The largest metastatic node is 2.5cm

Perinodal (extracapsular) extension identified

The largest metastatic deposit measures 2.5cm in greatest dimension

5. SP:Lymph nodes, paraaortic, resection:

Lymph Nodes:

Number of nodes examined:18

Number of metastatic nodes:13

The largest metastatic node is 3.5cm

Perinodal (extracapsular) extension identified

The largest metastatic deposit measures 3.5cm in greatest dimension

6. SP:Lymph nodes, aortocaval, resection:

Lymph Nodes:

Not involved

Number of nodes examined:4

7. SP: Hernia sac, abdomen, repair:

-Benign mesothelium lined fibrovascular and adipose tissue, consistent with hernia sac

Comment: The tumor cells are negative for CK7, 34BE12 and racemase, and show focal faint staining with AE1/AE3 and CA-IX. BAF-47 stain is non-contributory. Among the diagnostic possibilities, a hereditary leiomyoma renal cell carcinoma (HLRCC) should be considered. Selected parts (1, 2, 3 and 5) reviewed with [REDACTED] who concurs.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be used for investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

Special Studies:

Result

Special Stain

Comment

AE1:AE3

CK7

[page 3 of 5]
RACEMASE
34BE12
NEG CONT
IMM RECUT
BAF-47
CA-1X.
NEG CONT

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "caval wall rule out tumor invasion" and consists of tan-pink tissue measuring 0.9 x 0.4 x 0.1 cm. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

2) The specimen is received fresh and subsequently placed in formalin labeled "left kidney and adrenal gland, fresh and sterile" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1007 g in total. The kidney measures 19 x 12.5 x 8.5 cm. The attached ureter measures 9 cm in length and 0.2 cm in diameter. The attached renal vein measures 5.5 cm in length and 1.7 cm in diameter. The arterial and ureteral margins are grossly unremarkable. The vein is dilated with firm, adherent, yellow-red possible blood clot obstructing the lumen. Also in the pelvis are multiple firm to rubbery nodules, some of which appear to be positive lymph nodes. An orange-yellow, hemorrhagic adrenal gland is identified near the hilum and measures 5 x 3 x 1.5 cm. The kidney is inked black and bivalved to reveal an 8.5 x 7.5 x 6 cm yellow-tan to red-brown, hemorrhagic, friable, pseudoencapsulated mass in the upper pole which grossly invades through the renal capsule. Scattered are multiple ovoid, circumscribed lesions which grossly involve the pelvis. Sections through the remainder of the kidney reveals scant, uninvolved pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures up to 1.2 cm and the calyces are almost entirely infiltrated with tumor. Also in the container are multiple, irregular portions of red-yellow, friable, possibly necrotic soft tissue and red-brown blood clot representing possible additional portions of the upper pole tumor. The specimen is photographed. Representative sections are submitted for permanent sections.

Summary of sections:
UVM -- ureteral and vessel margins
UPT-- upper pole tumor
SL -- scattered lesions
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
UPTK -- upper pole tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney
AD -- adrenal gland

3) The specimen is received in formalin, labeled "Additional vena cava" and consists of a 1.2 x 0.4 x 0.3 cm, irregular, rubbery, pink-white tissue fragment, which is submitted in toto.

Summary of sections:
AVC -- additional vena cava

4) The specimen is received in formalin, labeled "Left perihilar lymph nodes" and consists of a 2.4 x 2.0 x 1.3 cm fragment of a tissue fragment, which is sectioned to reveal five, firm, red purple lymph nodes, ranging from 0.3 to 2.2 cm in greatest dimension. The larger lymph nodes are bisected or trisected and all lymph nodes are entirely submitted.

Summary of sections:
LN -- lymph nodes
BLN -- bisected lymph nodes
LTLN -- largest trisected lymph node, submitted into two cassettes

[page 4 of 5]
5) The specimen is received in formalin, labeled "Para-aortic lymph nodes" and consists of a 3.7 x 3.6 x 2.0 cm aggregate of fibrofatty tissue, which is sectioned to reveal 19, firm, slightly adhered to matted, tan-white lymph nodes, ranging from 0.3 to 2.6 cm in greatest dimension. The larger lymph nodes are bisected and all lymph nodes are entirely submitted.

Summary of sections:

LN -- lymph nodes

BLN -- bisected lymph nodes

LBLN -- largest bisected lymph node, submitted into two cassettes

6) The specimen is received in formalin, labeled "Aortocaval lymph nodes" and consists of a 2.6 x 1.1 x 0.7 cm fibrofatty tissue fragment, which is sectioned to reveal four, diffusely hemorrhagic, focally fragmented, tan-red lymph nodes, ranging from 0.7 to 1.2 cm in greatest dimension. All four lymph nodes are bisected and are entirely submitted.

Summary of sections:

BLN -- bisected lymph nodes

7) The specimen is received in formalin, labeled "Hernia sac -- abdomen" and consists of a 5.7 x 3.8 x 0.8 cm, irregular, rubbery, focally fatty, tan-purple fibromembranous tissue fragment, with multiple congested lobules of adipose tissue. No lesions or lymph nodes are identified grossly. Representative sections are submitted.

Summary of sections:

RS -- representative section

Summary of Sections:

Part 1: SP: Caval wall, biopsy

Block	Sect. Site	PCs
1	fsc	1

Part 2: SP: Kidney and adrenal gland, left, radical nephrectomy

Block	Sect. Site	PCs
2	AD	2
2	K	4
3	LN	3
1	PTK	1
3	RP	4
4	SL	4
1	THF	1
2	TSF	2
4	UPT	4
2	UVM	3

Part 3: SP: Vena cava, additional, biopsy

Block	Sect. Site	PCs
1	AVC	1

Part 4: SP: Lymph nodes, left perihilar, resection

Block	Sect. Site	PCs
2	BLN	4
2	LBLN	2
1	LN	2

Part 5: SP: Lymph nodes, paraaortic, resection

[page 5 of 5]
Block	Sect. Site	PCs
6	BLN	12
2	LBLN	2
2	LN	12

Part 6: SP: Lymph nodes, aortocaval, resection

Block	Sect. Site	PCs
4	BLN	8

Part 7: SP: Hernia sac, abdomen, repair

Block	Sect. Site	PCs
1	RS	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: Caval wall
PERMANENT DIAGNOSIS: SEE FINAL
-
-
-

Source: NCI Genomic Data Commons file c2be98c7-3c11-4766-b985-19426f080489 (TCGA-BQ-5889.1D46CB1C-791F-49BE-8A0E-1490D3005F93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).